Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A3J4, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A3J4-06A (Metastatic).

[page 1 of 2]
LABORATORY SERVICE

REPORT COPY
from

DEPARTMENT OF ANATOMICAL PATHOLOGY

Professor

Enquiries

REQUESTING DR :
VERIFIED BY :

SPECIMEN DATE
ACCESSION :

REPORTED BY

Reported by:

Previous Lab. Ref:

100-0-3

CLINICAL INFORMATION

Metastatic melanoma (L) groin nodule.

Melanoma NOS 8720/3
Site: subcutaneous, groin C49.5

OPERATION/NATURE OF SPEC

Wide excision + primary closure metastatic nodule (L) groin + 2 or 3 extra nodes.

MACROSCOPIC DESCRIPTION

"Left groin contents". An ellipse of skin, 87 x 16mm with attached subcutaneous fatty tissue 110mm long, 50mm deep and 17mm wide. A circle has been previously inked onto the skin ellipse and underlying this circle is a firm nodule which has been previously opened. The nodule measures 23 x 18 x 10mm, and its cut surface is firm, tan and partially haemorrhagic. The nodule is 1mm from a lateral surgical margin. Surgical margins inked blue.

A. Nodule with nearest surgical margin.

The remainder of the specimen was dissected for lymph nodes.

B&C. 1 node in five pieces.

D. 1 node in three pieces.

E. 1 node bisected.

Some tissue sent to tumour bank.

MICROSCOPIC DESCRIPTION

"Left groin contents". The subcutaneous nodule is metastatic non-pigmented malignant melanoma. Its epithelioid cells show frequent mitoses. The tumour appears completely excised.

The 3 lymph nodes (B-E) show no evidence of malignancy.

* Continued next page *

[page 2 of 2]
LABORATORY SERVICE

REPORT COPY
from

DEPARTMENT OF ANATOMICAL PATHOLOGY

Professor

Enquiries

REQUESTING DR :
Verified by :

SPECIMEN DATE
ACCESSION

MICROSCOPIC DESCRIPTION ...Cont'd

SNOMED CODES

Subcutaneous tissue - malignant melanoma, metastatic
Skin resection

***** END OF ACCESSION *****

Source: NCI Genomic Data Commons file 3e2232cb-bede-46fb-ac8e-43105a2da1bd (TCGA-EE-A3J4.E77781A9-A297-4BFF-B62B-C63DFFA5994E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).